Somatic mutation profile of tumor specimen ALCH-B1MW-TTP1-A (aliquot ALCH-B1MW-TTP1-A-1-0-D-A76B-36) from ALCHEMIST case ALCH-B1MW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 63.5 years (23,197 days).
Specimen ALCH-B1MW-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0040d90d-b70c-425a-a2ac-0bc62d50f724.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1MW-NB1-A (Blood Derived Normal), aliquot ALCH-B1MW-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a2b224b8-f5be-4df3-9721-9077e545c358

The open-access MAF lists 90 somatic variants for this specimen: 56 protein-altering or splice-affecting, 22 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 22, Intron 9, Nonsense Mutation 4, RNA 2, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHEK2 | c.1038-1G>A p.X346_splice (on ENST00000382580 / NM_001005735.2; = p.X303_splice on NM_007194.4) | Splice Site (SNP) | VAF 7/71 reads (10%) | catalogued as rs886039721, COSV60417098; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 20/215 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ADAMTS18 | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 30/301 reads (10%) | catalogued as COSV51401031; called by muse, mutect2
- CCDC125 | c.853G>A p.G285R | Missense Mutation (SNP) | VAF 32/309 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.046); catalogued as rs750610415; called by muse, mutect2, varscan2
- CTCFL | c.106T>A p.C36S | Missense Mutation (SNP) | VAF 42/474 reads (9%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as rs748979103; called by muse, mutect2
- DCBLD2 | c.2111C>T p.T704M | Missense Mutation (SNP) | VAF 33/394 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.475); catalogued as rs765661963; called by muse, mutect2
- EIF4E2 | c.9C>G p.N3K | Missense Mutation (SNP) | VAF 25/223 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as rs370961236; called by muse, mutect2, varscan2
- FAM135B | c.3725C>T p.T1242M | Missense Mutation (SNP) | VAF 43/374 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99424141; called by muse, mutect2, varscan2
- FHL3 | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 30/481 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV65952781; called by muse, mutect2
- GRIA4 | c.2117G>T p.R706M | Missense Mutation (SNP) | VAF 24/275 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as COSV56884135; called by muse, mutect2
- IGF2R | c.748G>T p.D250Y | Missense Mutation (SNP) | VAF 16/280 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV99052815; called by muse, mutect2
- IGKV1D-16 | c.262G>T p.G88* | Nonsense Mutation (SNP) | VAF 64/782 reads (8%) | catalogued as rs1371648473; called by muse, mutect2
- LTB4R2 | c.320C>T p.P107L (on ENST00000528054; = p.P76L on NM_019839.5) | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761907733; called by muse, mutect2, varscan2
- MYH15 | c.3964C>T p.R1322W | Missense Mutation (SNP) | VAF 19/382 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs374236023; called by muse, mutect2
- NOL4L | c.439G>A p.G147S | Missense Mutation (SNP) | VAF 26/260 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.32); catalogued as rs1370296209; called by muse, mutect2, varscan2
- OR4E2 | c.653A>G p.Y218C | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57731644, COSV57732030; called by muse, mutect2
- PAX2 | c.826G>A p.V276I (on ENST00000428433 / NM_003987.5; = p.V253I on NM_000278.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/727 reads (8%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.99); catalogued as rs770703982; called by muse, mutect2
- RAPGEF4 | c.1607T>C p.M536T | Missense Mutation (SNP) | VAF 22/296 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1380210048; called by muse, mutect2
- SLC38A10 | c.463G>T p.A155S | Missense Mutation (SNP) | VAF 54/370 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs751388851; called by muse, mutect2, varscan2
- SV2C | c.556C>A p.P186T | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.062); catalogued as COSV100455990; called by muse, mutect2
- TF | c.1781C>T p.A594V | Missense Mutation (SNP) | VAF 19/221 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1341678783, COSV53920087; called by muse, mutect2
- ZNF160 | c.1766G>T p.G589V | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62001090; called by muse, mutect2
- ADGRG4 | c.3442C>A p.P1148T | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- ASB18 | c.637C>A p.R213S | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- ATP1A4 | c.776A>T p.E259V | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- CERCAM | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 26/133 reads (20%) | called by muse, mutect2, varscan2
- DNAH5 | c.7342G>A p.E2448K | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2
- EPHA5 | c.2164C>A p.L722I | Missense Mutation (SNP) | VAF 20/330 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2
- EPHA5 | c.2163C>A p.F721L | Missense Mutation (SNP) | VAF 20/335 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FAM135B | c.1015C>G p.H339D | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FARP2 | c.1108A>T p.S370C | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.273); called by muse, mutect2
- FBN2 | c.2310T>A p.N770K | Missense Mutation (SNP) | VAF 19/330 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); called by muse, mutect2
- GLS2 | c.1778T>C p.L593P | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); called by muse, mutect2
- GRIA2 | c.2011T>G p.L671V | Missense Mutation (SNP) | VAF 24/231 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HCN3 | c.2045G>T p.S682I | Missense Mutation (SNP) | VAF 15/174 reads (9%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.133); called by muse, mutect2
- HIVEP2 | c.1562C>T p.A521V | Missense Mutation (SNP) | VAF 36/275 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- IDH1 | c.776T>C p.M259T | Missense Mutation (SNP) | VAF 45/396 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- KLF11 | c.1283G>C p.W428S | Missense Mutation (SNP) | VAF 39/468 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LIPT2 | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- MAGEB16 | c.85C>T p.Q29* | Nonsense Mutation (SNP) | VAF 9/92 reads (10%) | called by muse, mutect2, varscan2
- MARCHF10 | c.785G>T p.G262V | Missense Mutation (SNP) | VAF 62/433 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MINDY3 | c.124G>T p.A42S | Missense Mutation (SNP) | VAF 16/300 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2
- OR14K1 | c.373T>C p.C125R | Missense Mutation (SNP) | VAF 32/234 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- OSBPL7 | c.1661A>T p.K554M | Missense Mutation (SNP) | VAF 49/440 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- PCDH11Y | c.2591C>A p.A864D (on ENST00000400457 / NM_032973.2; = p.A853D on NM_032971.3) | Missense Mutation (SNP) | VAF 47/242 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SAGE1 | c.1972G>T p.A658S | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- SLC29A1 | c.215A>T p.E72V | Missense Mutation (SNP) | VAF 76/714 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.021); called by muse, mutect2
- SLC8A1 | c.1048A>T p.N350Y | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SLC8A2 | c.650C>A p.A217D | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.066); called by muse, mutect2
- SLU7 | c.948G>T p.R316S | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- SYT4 | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 27/348 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TEKT4 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- TRMO | c.713C>G p.A238G | Missense Mutation (SNP) | VAF 51/376 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TSR3 | c.470G>T p.G157V | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TSR3 | c.469G>T p.G157C | Missense Mutation (SNP) | VAF 23/242 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- UBE3A | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- ABCB11 | c.3907C>T p.L1303= | Silent (SNP) | VAF 24/429 reads (6%) | called by muse, mutect2
- ARHGAP30 | c.285G>A p.K95= | Silent (SNP) | VAF 17/179 reads (9%) | called by muse, mutect2
- ATN1 | c.162C>T p.A54= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs782631089, COSV100755683; called by muse, mutect2, varscan2
- BMP1 | c.1089C>T p.N363= | Silent (SNP) | VAF 17/152 reads (11%) | catalogued as rs1239805704; called by muse, mutect2, varscan2
- CRACDL | c.2361G>A p.R787= | Silent (SNP) | VAF 19/171 reads (11%) | called by muse, mutect2, varscan2
- CRAMP1 | c.2970G>T p.T990= | Silent (SNP) | VAF 32/275 reads (12%) | catalogued as COSV51960031; called by muse, mutect2, varscan2
- DPYS | c.1014G>A p.G338= | Silent (SNP) | VAF 32/416 reads (8%) | catalogued as rs1359207470; called by muse, mutect2
- HMCN1 | c.369T>A p.I123= | Silent (SNP) | VAF 28/361 reads (8%) | called by muse, mutect2
- LCP2 | c.681G>C p.T227= | Silent (SNP) | VAF 21/261 reads (8%) | called by muse, mutect2
- LY75 | c.576A>G p.P192= | Silent (SNP) | VAF 12/194 reads (6%) | catalogued as COSV55109139; called by muse, mutect2
- MIDEAS | c.465C>A p.V155= | Silent (SNP) | VAF 21/177 reads (12%) | called by muse, mutect2, varscan2
- NHSL1 | c.498A>G p.S166= | Silent (SNP) | VAF 21/181 reads (12%) | catalogued as rs943672689; called by muse, mutect2, varscan2
- OTOGL | c.4875C>A p.S1625= (on ENST00000547103; = p.S1616= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 8/109 reads (7%) | called by muse, mutect2
- PCNA | c.606A>G p.P202= | Silent (SNP) | VAF 14/168 reads (8%) | catalogued as COSV99176954; called by muse, mutect2
- POLE | c.1278G>A p.A426= | Silent (SNP) | VAF 30/299 reads (10%) | catalogued as rs1437075270; ClinVar: likely benign; called by muse, mutect2
- SHC4 | c.813C>G p.L271= | Silent (SNP) | VAF 7/100 reads (7%) | catalogued as COSV100194727; called by muse, mutect2
- SLC9C1 | c.555A>G p.T185= | Silent (SNP) | VAF 27/138 reads (20%) | called by muse, mutect2, varscan2
- SPATA31A1 | c.684C>A p.P228= | Silent (SNP) | VAF 41/494 reads (8%) | called by muse, mutect2, varscan2
- SYT4 | c.651A>T p.P217= | Silent (SNP) | VAF 24/347 reads (7%) | called by muse, mutect2
- TEX37 | c.294C>T p.D98= | Silent (SNP) | VAF 32/400 reads (8%) | catalogued as rs762328344; called by muse, mutect2
- TMEM117 | c.462A>G p.K154= | Silent (SNP) | VAF 14/166 reads (8%) | called by muse, mutect2
- ZNF225 | c.1638G>A p.G546= | Silent (SNP) | VAF 24/270 reads (9%) | called by muse, mutect2
- BOC | c.667+75G>T | Intron (SNP) | VAF 12/136 reads (9%) | called by muse, mutect2
- CASP3 | c.-16+3921G>T | Intron (SNP) | VAF 36/220 reads (16%) | catalogued as rs529271443; called by muse, mutect2, varscan2
- CCDC88C | c.4442-2226G>T | Intron (SNP) | VAF 38/418 reads (9%) | called by muse, mutect2
- DPP10 | c.61-147255C>A | Intron (SNP) | VAF 11/82 reads (13%) | called by muse, mutect2, varscan2
- HNRNPUL1 | c.1688-166del | Intron (DEL) | VAF 8/73 reads (11%) | called by mutect2, pindel
- LYST | c.4862+18A>T | Intron (SNP) | VAF 12/164 reads (7%) | called by muse, mutect2
- MCM3 | c.2259-551C>T | Intron (SNP) | VAF 16/179 reads (9%) | called by muse, mutect2
- MYO9A | c.5142+678C>G | Intron (SNP) | VAF 7/88 reads (8%) | called by muse, mutect2
- NOC2LP2 | n.840C>G | RNA (SNP) | VAF 14/410 reads (3%) | called by muse, mutect2
- OR2W5 | n.564G>A | RNA (SNP) | VAF 52/406 reads (13%) | called by muse, mutect2, varscan2
- RPL28 | c.205+150C>T | Intron (SNP) | VAF 10/160 reads (6%) | catalogued as rs369623186; called by muse, mutect2
- SHH | c.*2342C>A | 3'UTR (SNP) | VAF 17/168 reads (10%) | called by muse, mutect2, varscan2
